TCGA case TCGA-EE-A2GD — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c567ee6-bd57-448b-ad17-b74eb695b6f5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 58 years; Vital status: Dead; Days to death: 10,346 days (28.3 years).

Diagnoses (13)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.2; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: Progression; Age at diagnosis: 83.6 years (30,547 days); Days to diagnosis: 9,021 days (24.7 years); Prior treatment: No; Days to last follow up: 10,346 days (28.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Right; Classification of tumor: Synchronous primary.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.9 years (21,526 days); Year of diagnosis: 1984; AJCC staging edition: 2nd; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
5. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 69.0 years (25,215 days); Days to diagnosis: 3,689 days (10.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 3,689 days (10.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS.
6. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 74.9 years (27,344 days); Days to diagnosis: 5,818 days (15.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 5,818 days (15.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
7. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 75.5 years (27,564 days); Days to diagnosis: 6,038 days (16.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 6,038 days (16.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
8. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 79.1 years (28,887 days); Days to diagnosis: 7,361 days (20.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 7,361 days (20.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
9. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 79.3 years (28,975 days); Days to diagnosis: 7,449 days (20.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 7,449 days (20.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
10. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 79.5 years (29,038 days); Days to diagnosis: 7,512 days (20.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 7,512 days (20.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
11. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 79.9 years (29,178 days); Days to diagnosis: 7,652 days (21.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 7,652 days (21.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
12. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 83.6 years (30,547 days); Days to diagnosis: 9,021 days (24.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 9,021 days (24.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
13. Recurrence of diagnosis 4 (Malignant melanoma, NOS). Age at diagnosis: 86.7 years (31,669 days); Days to diagnosis: 10,143 days (27.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (11 entries)
- Day 3,689 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 3,689 days (10.1 years).
- Day 5,818 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 5,818 days (15.9 years).
- Day 6,038 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 6,038 days (16.5 years).
- Day 7,361 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 7,361 days (20.2 years).
- Day 7,449 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 7,449 days (20.4 years).
- Day 7,512 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 7,512 days (20.6 years).
- Day 7,652 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 7,652 days (21.0 years).
- Day 9,021 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 9,021 days (24.7 years).
- Days to follow up: 9,568 days (26.2 years); Disease response: With Tumor.
- Day 10,143 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 10,143 days (27.8 years).
- Days to follow up: 10,346 days (28.3 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A2GD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A2GD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-EE-A2GD-06A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A2GD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 4.4; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Leg; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 10,346 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 10,346 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,689 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A2GD-06A-11D-A194-01): tumor purity 0.43, ploidy 1.96, whole-genome doublings 0.
